MMRF case MMRF_2054 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/193de550-e410-4dfb-ae82-0f67f8644d97

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.6 years (23,248 days); ISS stage: II; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 576 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 288 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 289 days.
   Treatment given: Therapeutic agents: Carfilzomib + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 401 days (1.1 years); Days to treatment end: 576 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 730 days (2.0 years).
   Treatment given: Therapeutic agents: Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 730 days (2.0 years); Days to treatment end: 933 days (2.6 years).
   Treatment given: Therapeutic agents: Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 934 days (2.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 997.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 54.6 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 10.3 g/dL; Glucose 5.34 mmol/L.
- Day 85: M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 48.1 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.03 mmol/L; Albumin 28 g/L; Total Protein 9.5 g/dL; Glucose 5.39 mmol/L.
- Day 176 (ECOG 2): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 7.21 mmol/L.
- Day 273 (ECOG 0): Hemoglobin 5.21 mmol/L; Leukocytes 0.4 ×10⁹/L; Absolute Neutrophil 0.04 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 7.6 g/dL; Glucose 7.92 mmol/L.
- Day 346 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 19.1 g/L; Immunoglobulin A 0.059 g/L; Immunoglobulin M 0.059 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 7.9 g/dL; Glucose 6.44 mmol/L.
- Day 443 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 20.4 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 3.91 mmol/L.
- Day 541 (ECOG 0): Hemoglobin 6.57 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 327 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 616 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 3.55 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 709 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 6.44 mmol/L.
- Day 801: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 3.8 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 5.06 mmol/L.
- Day 849: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.61 mmol/L.
- Day 961: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 2.6 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 6.99 mmol/L.

Other clinical attributes
- Day -4: Weight: 82 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2054_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2054_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
